Gene-level copy-number profile of tumor specimen TCGA-CX-7219-01A from TCGA case TCGA-CX-7219, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.2 years (17,222 days).
Specimen TCGA-CX-7219-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e6e8a1cb-3529-4eca-bfd3-dd804d7575da.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CX-7219-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 397 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4326fd81-8129-4bd6-a2bf-7a0c698a15c7

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 2,435; copy number 1: 28,925; copy number 2: 27,170; copy number 3: 1,036; copy number 4: 660.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CX-7219-01A-11D-2010-01): tumor purity 0.55, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:97,545,701–97,856,825, 5 genes: SEC63P1, RPL26P9, AC114878.1, DPYD-AS2, AC114878.2.
- chr1:196,774,813–196,832,189, 2 genes: CFHR3, CFHR1.
- chr7:64,180,006–64,434,592, 10 genes: VN1R38P, SAPCD2P1, ZNF735, ZNF679, AC073270.1, ZNF736, TRIM60P18, AC073270.2, AC022202.1, YWHAEP1.
- chr9:21,512,115–23,672,387, 28 genes (within-gene range 0–2): MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2.
- chr9:113,102,117–113,119,928, 2 genes: FAM225B, FAM225A.
- chr18:50,959,267–51,283,896, 7 genes: Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 1,696 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:110,945,109–112,798,691, 39 genes, copy number 3: LYPLA1P2, AC004062.1, RNU6-289P, AC083795.1, AC083795.2, AC139718.2, AC139718.1, AC004704.1, CCDC34P1, TUBB8P3, AC093663.1, FAM241A, AC093663.2, AC109347.1, AP1AR, AC109347.2, TIFA, ALPK1, RTEL1P1, TOX4P1, NEUROG2, NEUROG2-AS1, RPL23AP94, ZGRF1, H3P14, LARP7, MIR302CHG, MIR367, MIR302D, MIR302A, MIR302C, MIR302B, OSTCP4, AC106864.1, WRBP1, AC017007.3, Y_RNA, RPL7AP30, AC017007.4.
- chr4:112,826,307–112,827,607, 1 gene, copy number 3: AC017007.2.
- chr7:92,412,550–113,494,870, 456 genes, copy number 3–4 (broad region; genes not listed).
- chr8:99,613,783–142,403,182, 553 genes, copy number 4 (within-gene range 2–4) (broad region; genes not listed).
- chr8:142,657,460–145,066,685, 157 genes, copy number 3 (broad region; genes not listed).
- chr9:27,829,276–33,248,567, 56 genes, copy number 3–4 (within-gene range 1–4): AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4.
- chr9:38,804,007–41,701,096, 84 genes, copy number 3 (broad region; genes not listed).
- chr13:94,574,054–114,337,626, 316 genes, copy number 3 (broad region; genes not listed).
- chr16:65,861,112–65,863,784, 1 gene, copy number 3 (within-gene range 2–3): AC022164.1.
- chr17:36,103,827–36,457,535, 19 genes, copy number 4: CCL4, RN7SL301P, AC243829.2, AC243829.7, TBC1D3B, AC243829.1, CCL3L3, CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, RNU6-1192P, TBC1D3F, TBC1D3J.
- chr18:22,586,465–23,437,961, 13 genes, copy number 4 (within-gene range 2–4): RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1.
- chr19:33,283,978–33,285,739, 1 gene, copy number 3: AC008738.6.

Autosomal genes at a single copy (total copy number 1): 28,888. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
